CCDI case PBBWYT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/e04e0602-2613-442b-b12e-bd11c6a11577

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Desmoplastic small round cell tumor: ICD-O-3 morphology code: 8806/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 9.5 years (3,469 days).

Biospecimens (3 samples)
- Sample 0DJVOX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJVP8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJVPM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
